TCGA case TCGA-EE-A29B — Skin Cutaneous Melanoma (TCGA-SKCM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Nevi and Melanomas; Primary site: Skin; Tissue source site: University of Sydney. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/905ea29f-588a-497b-9f06-2eef3bdc9442

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Australia; Age at index: 67 years; Vital status: Dead; Days to death: 2,588 days (7.1 years).

Diagnoses (28)
1. Malignant melanoma, NOS (the primary disease): ICD-O-3 morphology code: 8720/3; ICD-10 code: C44.7; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Skin of lower limb and hip; Classification of tumor: metastasis; Age at diagnosis: 73.3 years (26,769 days); Days to diagnosis: 2,151 days (5.9 years); Prior treatment: No; Days to last follow up: 2,588 days (7.1 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, prior to procurement; Radiation Therapy, NOS, prior to procurement.
2. Malignant melanoma, NOS: Tissue or organ of origin: Skin, NOS; Classification of tumor: primary; Clark level: III; Sites of involvement: Skin, Extremities; Ulceration indicator: Yes.
   Pathology details: Breslow thickness category: >2.0-4.0 mm.
   Recorded as not given: Radiation Therapy, NOS.
3. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 67.4 years (24,618 days); Year of diagnosis: 2004; AJCC staging edition: 6th; AJCC pathologic T: T3b; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Melanoma known primary: Yes.
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
4. Melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Classification of tumor: Subsequent Primary; Age at diagnosis: 68.7 years (25,108 days); Days to diagnosis: 490 days (1.3 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 539 days (1.5 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, for initial diagnosis; Radiation Therapy, NOS, for initial diagnosis.
5. Recurrence of diagnosis 3 (Malignant melanoma, NOS). Age at diagnosis: 69.4 years (25,364 days); Days to diagnosis: 746 days (2.0 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Recurrent Disease; Days to treatment start: 746 days (2.0 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease.
6. Recurrence of diagnosis 3 (Malignant melanoma, NOS). Age at diagnosis: 69.5 years (25,390 days); Days to diagnosis: 772 days (2.1 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Recurrent Disease; Days to treatment start: 772 days (2.1 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease.
7. Recurrence of diagnosis 3 (Malignant melanoma, NOS). Age at diagnosis: 69.7 years (25,469 days); Days to diagnosis: 851 days (2.3 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Recurrent Disease; Days to treatment start: 851 days (2.3 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease.
8. Recurrence of diagnosis 3 (Malignant melanoma, NOS). Age at diagnosis: 70.1 years (25,588 days); Days to diagnosis: 970 days (2.7 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Recurrent Disease; Days to treatment start: 970 days (2.7 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease.
9. Recurrence of diagnosis 3 (Malignant melanoma, NOS). Age at diagnosis: 70.3 years (25,684 days); Days to diagnosis: 1,066 days (2.9 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Recurrent Disease; Days to treatment start: 1,066 days (2.9 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease.
10. Recurrence of diagnosis 3 (Malignant melanoma, NOS). Age at diagnosis: 70.6 years (25,774 days); Days to diagnosis: 1,156 days (3.2 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Recurrent Disease; Days to treatment start: 1,156 days (3.2 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease.
11. Recurrence of diagnosis 3 (Malignant melanoma, NOS). Age at diagnosis: 70.9 years (25,889 days); Days to diagnosis: 1,271 days (3.5 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Recurrent Disease; Days to treatment start: 1,271 days (3.5 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease.
12. Recurrence of diagnosis 3 (Malignant melanoma, NOS). Age at diagnosis: 71.8 years (26,242 days); Days to diagnosis: 1,624 days (4.4 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Recurrent Disease; Days to treatment start: 1,624 days (4.4 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease.
13. Recurrence of diagnosis 3 (Malignant melanoma, NOS). Age at diagnosis: 72.4 years (26,441 days); Days to diagnosis: 1,823 days (5.0 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Recurrent Disease; Days to treatment start: 1,823 days (5.0 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease.
14. Recurrence of diagnosis 3 (Malignant melanoma, NOS). Age at diagnosis: 72.5 years (26,481 days); Days to diagnosis: 1,863 days (5.1 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Recurrent Disease; Days to treatment start: 1,863 days (5.1 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease.
15. Recurrence of diagnosis 3 (Malignant melanoma, NOS). Age at diagnosis: 72.8 years (26,606 days); Days to diagnosis: 1,988 days (5.4 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Recurrent Disease; Days to treatment start: 1,988 days (5.4 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease.
16. Metastasis of diagnosis 3 (Malignant melanoma, NOS), site: Thorax, NOS. Age at diagnosis: 72.9 years (26,641 days); Days to diagnosis: 2,023 days (5.5 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 2,023 days (5.5 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease.
17. Recurrence of diagnosis 3 (Malignant melanoma, NOS). Age at diagnosis: 73.2 years (26,739 days); Days to diagnosis: 2,121 days (5.8 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Recurrent Disease; Days to treatment start: 2,121 days (5.8 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease.
18. Metastasis of diagnosis 3 (Malignant melanoma, NOS), site: Lower limb, NOS. Age at diagnosis: 73.3 years (26,769 days); Days to diagnosis: 2,151 days (5.9 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 2,151 days (5.9 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease.
19. Metastasis of diagnosis 3 (Malignant melanoma, NOS), site: Lower limb, NOS. Age at diagnosis: 73.4 years (26,813 days); Days to diagnosis: 2,195 days (6.0 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 2,195 days (6.0 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease.
20. Metastasis of diagnosis 3 (Malignant melanoma, NOS), site: Thorax, NOS. Age at diagnosis: 73.8 years (26,952 days); Days to diagnosis: 2,334 days (6.4 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 2,334 days (6.4 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease.
21. Metastasis of diagnosis 3 (Malignant melanoma, NOS), site: Retroperitoneum. Age at diagnosis: 73.9 years (27,006 days); Days to diagnosis: 2,388 days (6.5 years); Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.
22. Metastasis of diagnosis 3 (Malignant melanoma, NOS), site: Pelvis, NOS. Age at diagnosis: 73.9 years (27,006 days); Days to diagnosis: 2,388 days (6.5 years); Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.
23. Metastasis of diagnosis 3 (Malignant melanoma, NOS), site: Other ill-defined sites. Age at diagnosis: 73.9 years (27,006 days); Days to diagnosis: 2,388 days (6.5 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 2,334 days (6.4 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease.
24. Metastasis of diagnosis 3 (Malignant melanoma, NOS), site: Liver. Age at diagnosis: 73.9 years (27,006 days); Days to diagnosis: 2,388 days (6.5 years); Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.
25. Metastasis of diagnosis 3 (Malignant melanoma, NOS), site: Thorax, NOS. Age at diagnosis: 73.9 years (27,006 days); Days to diagnosis: 2,388 days (6.5 years); Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.
26. Metastasis of diagnosis 3 (Malignant melanoma, NOS), site: Intrathoracic lymph nodes. Age at diagnosis: 73.9 years (27,006 days); Days to diagnosis: 2,388 days (6.5 years); Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.
27. Metastasis of diagnosis 3 (Malignant melanoma, NOS), site: Abdomen, NOS. Age at diagnosis: 73.9 years (27,006 days); Days to diagnosis: 2,388 days (6.5 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 2,388 days (6.5 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease.
28. Metastasis of diagnosis 3 (Malignant melanoma, NOS), site: Lower limb, NOS. Age at diagnosis: 74.1 years (27,064 days); Days to diagnosis: 2,446 days (6.7 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 2,446 days (6.7 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease.

Follow-up (26 entries)
- Day 746 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 746 days (2.0 years).
- Day 772 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 772 days (2.1 years).
- Day 851 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 851 days (2.3 years).
- Day 970 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 970 days (2.7 years).
- Day 1,066 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 1,066 days (2.9 years).
- Day 1,156 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 1,156 days (3.2 years).
- Day 1,271 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 1,271 days (3.5 years).
- Day 1,624 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 1,624 days (4.4 years).
- Day 1,823 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 1,823 days (5.0 years).
- Day 1,863 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 1,863 days (5.1 years).
- Day 1,988 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 1,988 days (5.4 years).
- Day 2,023 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Thorax, NOS; Days to progression: 2,023 days (5.5 years).
- Day 2,121 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 2,121 days (5.8 years).
- Day 2,151 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lower limb, NOS; Days to progression: 2,151 days (5.9 years).
- Day 2,195 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lower limb, NOS; Days to progression: 2,195 days (6.0 years).
- Day 2,334 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Thorax, NOS; Days to progression: 2,334 days (6.4 years).
- Day 2,388 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Abdomen, NOS; Days to progression: 2,388 days (6.5 years).
- Day 2,388 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Intrathoracic lymph nodes; Days to progression: 2,388 days (6.5 years).
- Day 2,388 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Other ill-defined sites; Days to progression: 2,388 days (6.5 years).
- Day 2,388 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Thorax, NOS; Days to progression: 2,388 days (6.5 years).
- Day 2,388 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Pelvis, NOS; Days to progression: 2,388 days (6.5 years).
- Day 2,388 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Retroperitoneum; Days to progression: 2,388 days (6.5 years).
- Day 2,388 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Liver; Days to progression: 2,388 days (6.5 years).
- Day 2,446 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lower limb, NOS; Days to progression: 2,446 days (6.7 years).
- Days to follow up: 2,452 days (6.7 years); Disease response: With Tumor.
- Days to follow up: 2,588 days (7.1 years); Disease response: With Tumor.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-EE-A29B-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-EE-A29B-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT; Initial weight: 180 mg.
  Slide TCGA-EE-A29B-06A-01-TSA: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 0.
- Sample TCGA-EE-A29B-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: With tumor; Breslow thickness at diagnosis: 4; Radiation therapy to primary: No; Primary location: Distant Metastasis; Metastatic tumor site: Left thigh; Primary melanoma skin type: Non-glabrous skin; Prior radiation therapy: No; History neoadjuvant treatment: No.
- Sites of primary melanomas: Primary multiple at diagnosis: No.
- Sites of primary melanomas, Site: Submitted tumor site: Extremities.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor; Subsequent known primaries: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 2,588 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 2,588 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 490 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-EE-A29B-06A-11D-A191-01): tumor purity 0.97, ploidy 2.06, whole-genome doublings 0.
